CCDI case PBCVJJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/455bdd7f-6aa2-49ae-a8f6-38b96fd78eb3

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E0UHH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E0UHU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E0UI2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
